Surgical pathology report (de-identified scan), TCGA case TCGA-08-0244, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0244-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, right parietal tumor, biopsy: Infiltrating glioblastoma multiforme and fragments of necrosis.
- B. Brain, tumor, biopsy: Glioblastoma multiforme, grade IV (WHO).
- C. Brain, tumor, resection: Glioblastoma multiforme, grade IV (WHO).
- D. Brain, "ex 2," biopsy: Necrosis, vascular proliferation, and macrophage infiltrate.
- E. Brain, "ex 3," biopsy: Glioblastoma, grade IV (WHO).
- F. Brain, "ex 4," biopsy: Necrosis, vascular proliferation, and focal atypical cells.
- G. Brain, "ex 5," biopsy: Necrosis, microvascular proliferation, and focal atypical cells.
- H. Brain, right parietal, biopsy: Glioblastoma multiforme, grade IV (WHO).

COMMENT: This is a highly cellular astrocytic neoplasm. The cells show both cytoplasmic and nuclear pleomorphism with both fibrillary and gemistocytic features. Abundant endothelial proliferation as well as areas of necrosis are present. An immunohistochemical stain for glial fibrillary acidic protein is strongly positive (C1).

In Part B, the endothelial proliferation is best seen on the frozen section slide. Part E is not as cellular as other regions. In Part H, the adjacent cortex is less involved but does show infiltrating tumor.

While the majority of the tissue in Parts F and G is necrotic, there are some viable, atypical cells around vessels which are consistent with the glioblastoma cells, but are not diagnostic.

By the [REDACTED] criteria, this is a glioblastoma multiforme; by the [REDACTED] criteria, it is a grade 4

[page 2 of 3]
ADDENDUM**Date of Addendum:** **Addendum Comment**

The MIB-1 immunohistochemical labeling is 13.04%.

[page 3 of 3]
astrocytoma. Stains for MIB 1, 53, and EGFR have been ordered and results will be reported in an addendum.

Intraoperative Diagnosis

FS1 (A) Brain, left parietal occipital lobe, biopsy: Infiltrating astrocytoma with marked nuclear atypia. Small component, grade II, suggest additional frozen preparations. Tissue section and cytologic prep. [REDACTED]

FS2 (B) Brain, left parietal occipital lobe, biopsy: WHO glioblastoma multiforme, grade IV. Tissue sections. [REDACTED]

Gross Description

The specimen is received in eight parts, each labeled with the patient's name and medical record number.

Part A, additionally labeled "tumor right parietal," is received fresh for frozen section diagnosis and consists of a single irregularly shaped fragment of red-gray soft tissue, measuring 2.0 x 1.2 x 0.7 cm. A representative section is frozen for frozen section diagnosis #1, with the frozen section remnant submitted in cassette A1. The remainder of the unfrozen tissue is submitted entirely in cassette A2.

Part B is received fresh for frozen section diagnosis #2 and consists of two irregularly shaped fragments of tan-red soft tissue, measuring 0.7 x 0.8 x 0.3 cm in aggregate. The specimen is entirely frozen for frozen section diagnosis #2, with the frozen section remnant submitted in cassette B1.

Part C, additionally labeled "tumor ex 1 perm," is received in formalin and consists of a single irregularly shaped fragment of soft, tan-yellow tissue, measuring 2.0 x 1.5 x 0.6 cm. The specimen is bisected and entirely submitted in cassette C1.

Part D, additionally labeled "permanent ex 2," is received in formalin and consists of a single rectangular fragment of soft, tan-pink tissue, measuring 1.0 x 0.4 x 0.3 cm. The specimen is entirely submitted in cassette D1.

Part E, additionally labeled "tumor perm ex 3," is received in formalin and consists of a single rectangular fragment of soft, tan-pink tissue, measuring 1.1 x 0.5 x 0.3 cm. The specimen is entirely submitted in cassette E1.

Part F, additionally labeled "tumor ex 4 perm," is received in formalin and consists of a single irregularly shaped fragment of soft, tan-pink tissue, measuring 1.0 x 0.5 x 0.4 cm. The specimen is entirely submitted in cassette F1.

Part G, additionally labeled "ex 5 perm," is received in formalin and consists of a single irregularly shaped fragment of soft, pink-tan tissue, measuring 0.5 x 0.3 x 0.2 cm. The specimen is entirely submitted in cassette G1.

Part H, additionally labeled "tumor (perm) right parietal," is received in formalin and consists of multiple irregularly shaped fragments of friable, pink-tan tissue, measuring 1.0 x 0.8 x 0.4 cm in aggregate. The specimen is entirely submitted in cassette H1.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing.

Clinical History

The patient is a [REDACTED] with a right parietal tumor, who undergoes resection.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Source: NCI Genomic Data Commons file bb9f9c44-3c6d-4f0a-9cb8-2e2bbf64e06d (TCGA-08-0244.816CFB3D-9D9B-4EE9-9A67-4BD086ED70D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).